Surgical pathology report (de-identified scan), TCGA case TCGA-YB-A89D, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Spectrum Health, specimen TCGA-YB-A89D-01A (Primary Tumor).

[page 1 of 2]
Research Gross Description

male with pancreatic mass

Research Dx

Pancreas, stomach, small intestine, pancreaticoduodenectomy:

Adenocarcinoma.

See case summary.

CASE SUMMARY FOR CARCINOMA OF EXOCRINE PANCREAS:

Specimen: Portions of pancreas, stomach, small intestine

Procedure: Whipple resection

Tumor site: Pancreas, with extension into ampulla and duodenal wall

Tumor size: Approximately 3.2 x 2.5 x 2.0 cm

Histologic type: Ductal adenocarcinoma

Histologic grade: G2: Moderately differentiated

Microscopic tumor extension: Tumor invades peripancreatic soft tissues

Margins:

Proximal margin (gastric or duodenal): Negative for carcinoma

Distal margin (distal duodenal): Negative for carcinoma

Uncinate process (retroperitoneal) margin (nonperitonealized surface of the uncinate process):
Negative for carcinoma

Bile duct margin: Negative for carcinoma

Pancreatic resection margin: Negative for carcinoma

Distance of invasive carcinoma from closest margin: 4 mm

Specify margin: Uncinate

Treatment effect: Not applicable

Lymphovascular invasion: Indeterminate

Perineural invasion: Present

Pathologic staging (pTNM)

Primary tumor (pT): pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

Regional lymph nodes (pN): pN1: Regional lymph node metastases

Number examined: 17

Number involved: 4

Distant metastasis (pM): pM: Not applicable

AJCC Staging (7th edition): pT3 pN1 pM: Not applicable

Research QC

Tumor:

70% tumor nuclei

5% necrosis

25% normal pancreas and stroma

Normal:

100% duct, stroma, adipose

Research Specimen

ICD O-3
Adenocarcinoma, duct NOS
8500/3
Date 4/25/13
Path
Pancreas C25.9
JW 11/22/13

[page 2 of 2]
Specimen Process Time

Blood draw time:

Plasma frozen time:

Serum frozen time:

Buffy coat frozen time:

Tissue:

Cold ischemia start time:

Formalin fixation start time:

Frozen start time:

Total cold ischemia time:

Formalin fixation stop time:

Total formalin fixation time:

Specimen Weight

Normal

1-181 mg

Tumor

1-187 mg, 2-290 mg

Specimen Size

Plasma x 3

Serum x 2

Buffy coat x 1

Cryovials x 3

Normal x 1

Tumor x 2

Metastatic x 0

FFPE x 3

Normal x 1

Tumor x 2

Metastatic x 0

Study

Patient Consent

Yes

Source: NCI Genomic Data Commons file 5e85407d-b98c-4e65-a897-090d233badb2 (TCGA-YB-A89D.385946B6-CD7F-45B5-BD72-AB6FDDCC9AB5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).